Gene-level copy-number profile of tumor specimen TCGA-61-2000-01A from TCGA case TCGA-61-2000, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.7 years (24,723 days).
Specimen TCGA-61-2000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7117504b-bdff-41de-8ca0-581fa89ee376.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2000-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30dfcc1c-e279-43c2-84ff-00ab220634e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 11,627; copy number 2: 35,330; copy number 3: 8,645; copy number 4: 1,984; copy number 5: 1,520; copy number 6: 432; copy number 7: 134; copy number 8: 28; copy number 9: 42; copy number 11: 43; copy number 14: 4; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2000-01A-01D-0663-01): tumor purity 0.92, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:30,970,984–30,999,911, 1 gene (within-gene range 0–2): RNF135.
- chr17:31,008,154–31,538,211, 14 genes (within-gene range 0–2): AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,166 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,206,765–14,400,963, 93 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:17,877,847–18,361,616, 1 gene, copy number 5 (within-gene range 4–5): KCNS3.
- chr2:18,403,967–22,536,322, 64 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:23,927,285–25,697,188, 45 genes, copy number 5: UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, AC093798.1, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14, DNAJC27-AS1, AC013267.1, Y_RNA, EFR3B, RN7SL856P, SUCLA2P3, POMC, LINC01381, DNMT3A, MIR1301, ARNILA, DTNB, DTNB-AS1, Y_RNA.
- chr2:28,307,063–69,962,265, 671 genes, copy number 5–14 (broad region; genes not listed).
- chr2:176,077,472–176,339,077, 21 genes, copy number 5: EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67.
- chr2:176,506,245–176,612,249, 4 genes, copy number 5: AC017048.1, AC017048.2, MIR1246, AC017048.3.
- chr2:211,298,941–211,299,189, 1 gene, copy number 5: RPS27P10.
- chr2:211,535,653–211,535,769, 1 gene, copy number 5: RNA5SP119.
- chr3:166,569,693–170,860,380, 71 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:170,459,548–170,586,075, 2 genes, copy number 9: SLC7A14, KRT8P13.
- chr4:2,418,974–3,040,760, 15 genes, copy number 5: CFAP99, RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4.
- chr4:3,044,101–3,074,538, 4 genes, copy number 5: RNU6-204P, HTT-AS, AL390065.2, AL390065.1.
- chr4:64,914,281–65,860,204, 11 genes, copy number 5 (within-gene range 2–5): LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1.
- chr5:151,276,358–151,686,975, 14 genes, copy number 5 (within-gene range 3–5): SLC36A3, SLC36A2, ATP6V1G1P5, AC034205.2, AC034205.1, AC034205.3, SLC36A1, RNA5SP197, FAT2, AC011337.1, MIR6499, AC011374.3, AC011374.1, SPARC.
- chr6:20,401,879–21,521,414, 13 genes, copy number 5 (within-gene range 3–5): E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581.
- chr8:108,572,643–110,556,518, 22 genes, copy number 5: AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1.
- chr8:125,859,721–130,443,674, 67 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr8:132,866,958–133,756,646, 18 genes, copy number 5 (within-gene range 4–5): TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49.
- chr8:135,234,131–145,066,685, 230 genes, copy number 5–6 (broad region; genes not listed).
- chr11:28,702,607–30,850,559, 24 genes, copy number 6 (within-gene range 1–6): LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1.
- chr11:37,938,601–39,261,213, 9 genes, copy number 5: LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P.
- chr11:123,882,920–124,266,218, 23 genes, copy number 5 (within-gene range 2–5): TMEM225, OR8D4, OR4D5, OR6T1, OR10S1, OR10G6, OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P, OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5.
- chr12:119,593,774–119,959,754, 7 genes, copy number 6: TMEM233, RN7SKP197, PRKAB1, CIT, AC002563.1, MIR1178, RPL35AP30.
- chr12:120,018,900–120,019,261, 1 gene, copy number 6: Metazoa_SRP.
- chr16:7,614,230–8,112,756, 3 genes, copy number 5 (within-gene range 4–5): AC005774.2, AC005774.1, AC093515.1.
- chr17:51,630,313–52,160,017, 1 gene, copy number 5 (within-gene range 2–5): CA10.
- chr17:52,390,515–54,365,634, 9 genes, copy number 5 (within-gene range 2–6): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1.
- chr17:54,477,796–56,511,659, 24 genes, copy number 6: ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2.
- chr18:47,285,725–47,594,550, 4 genes, copy number 5 (within-gene range 3–5): MIR4527HG, MIR4527, AC102797.2, AC102797.1.
- chr19:8,173,272–12,551,474, 246 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:14,380,501–19,113,030, 262 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:31,797,666–32,587,453, 10 genes, copy number 5 (within-gene range 3–5): LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5.
- chr19:32,608,337–32,608,469, 1 gene, copy number 5: SNORA68B.
- chr19:33,795,933–35,684,201, 101 genes, copy number 6 (broad region; genes not listed).
- chr22:28,459,869–30,428,990, 73 genes, copy number 5–15 (within-gene range 4–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
